Somatic mutation profile of tumor specimen TCGA-FD-A3SM-01A (aliquot TCGA-FD-A3SM-01A-11D-A22Z-08) from TCGA case TCGA-FD-A3SM, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 70.8 years (25,852 days).
Specimen TCGA-FD-A3SM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d1ea19a-a2c6-42e9-93e0-6969ff32bb05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3SM-10A (Blood Derived Normal), aliquot TCGA-FD-A3SM-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc5060b8-5ae0-410c-904f-f389083c3ff9

The open-access MAF lists 209 somatic variants for this specimen: 164 protein-altering or splice-affecting, 41 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 133, Silent 41, Nonsense Mutation 14, Frame Shift Del 6, Splice Site 3, Splice Region 3, Frame Shift Ins 2, RNA 2, Translation Start Site 2, In Frame Del 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LTBP2 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as rs137854855, CM126924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.4471C>T p.R1491* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as rs758517117, COSV60786626; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.3434A>G p.H1145R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.917); catalogued as rs1376263715, COSV70027841; called by muse, mutect2, varscan2
- ACTC1 | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as CM086760, COSV51758806; called by muse, mutect2, varscan2
- ADAMTS3 | c.1205A>G p.H402R | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs759406845, COSV54390362; called by muse, mutect2
- AFF1 | c.3283A>G p.I1095V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1197406377, COSV57119400; called by muse, mutect2, varscan2
- AHNAK2 | c.8262G>T p.K2754N | Missense Mutation (SNP) | VAF 99/279 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV60908509; called by muse, mutect2, varscan2
- AKR1C3 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as rs1554786278, COSV101003065; called by muse, mutect2, varscan2
- ALOX12B | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV59871031, COSV59872565; called by muse, mutect2, varscan2
- ANKRD27 | c.2415G>C p.K805N | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); catalogued as COSV60131238; called by muse, mutect2, varscan2
- ASL | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV100508787, COSV59188377; called by muse, mutect2, varscan2
- BCL9 | c.1038G>C p.E346D | Missense Mutation (SNP) | VAF 79/263 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV52343722; called by muse, mutect2, varscan2
- BRD1 | c.1154G>A p.C385Y | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53457079; called by muse, mutect2, varscan2
- C1orf35 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV55254685; called by muse, mutect2, varscan2
- CAB39L | c.10dup p.M4Nfs*5 | Frame Shift Ins (INS) | VAF 14/68 reads (21%) | catalogued as rs1270111731; called by mutect2, varscan2
- CCDC181 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV63155756, COSV63156325; called by muse, mutect2, varscan2
- CCZ1 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV58073913, COSV58075374; called by muse, mutect2, varscan2
- CDH23 | c.9472G>C p.E3158Q | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV56461112; called by muse, mutect2, varscan2
- CDH5 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as rs781712628, COSV58515833; called by muse, mutect2, varscan2
- CHIT1 | c.326T>A p.M109K | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV55146733; called by muse, mutect2, varscan2
- CLEC10A | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | catalogued as COSV99645022; called by muse, mutect2, varscan2
- CNOT3 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55362662; called by muse, mutect2, varscan2
- COQ3 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV54639634; called by muse, mutect2, varscan2
- CPNE6 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV53743895; called by muse, mutect2, varscan2
- CRAMP1 | c.2428C>G p.P810A | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1462706562, COSV51961831; called by muse, mutect2, varscan2
- CREBBP | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV52122091, COSV52134775; called by muse, mutect2, varscan2
- CTDSPL2 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV52945987; called by muse, mutect2, varscan2
- DAAM2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV51314042; called by muse, mutect2, varscan2
- DCLRE1A | c.1372C>T p.L458F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV63748629; called by muse, mutect2, varscan2
- DDIT4L | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV56767304; called by muse, mutect2, varscan2
- DDX1 | c.1016G>C p.G339A | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51839692; called by muse, mutect2, varscan2
- DENND5B | c.3646C>A p.R1216S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV60900651, COSV60902248; called by muse, mutect2, varscan2
- DGAT1 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60047645; called by muse, mutect2, varscan2
- DISP1 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV52658281; called by muse, mutect2, varscan2
- DNAH9 | c.5215G>C p.E1739Q | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); catalogued as rs777806746, COSV52347578; called by muse, mutect2, varscan2
- DNAJC13 | c.1783G>C p.E595Q | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV53449825; called by muse, mutect2, varscan2
- DNHD1 | c.13534G>A p.G4512S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54434623; called by muse, mutect2, varscan2
- DST | c.3928G>A p.E1310K (on ENST00000361203 / NM_001374722.1; = p.E984K on NM_001723.6) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV55011518; called by muse, mutect2, varscan2
- DUSP28 | c.312G>C p.K104N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.988); catalogued as rs761424683, COSV56033515; called by muse, mutect2, varscan2
- EEF1AKNMT | c.331C>T p.P111S (on ENST00000361735 / NM_015935.5; = p.P25S on NM_014955.3) | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.473); catalogued as rs774852088, COSV62282954; called by muse, mutect2, varscan2
- EFNA5 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV60949124; called by muse, mutect2, varscan2
- ELAPOR1 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV64040366; called by muse, mutect2, varscan2
- ENTPD7 | c.1373G>A p.R458K | Missense Mutation (SNP) | VAF 95/277 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV65112238; called by muse, mutect2, varscan2
- EP300 | c.3667C>G p.Q1223E | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV54331877, COSV54336120; called by muse, mutect2, varscan2
- EVC | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs145645536; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EVPL | c.3439G>A p.G1147R | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV56910405; called by muse, mutect2, varscan2
- EXOC8 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV50477707, COSV50478072; called by muse, mutect2, varscan2
- FAT3 | c.4877G>A p.C1626Y | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV53105110; called by muse, mutect2, varscan2
- FKBP8 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV55892120; called by muse, varscan2
- FKBP8 | c.294G>A p.G98= | Splice Region (SNP) | VAF 68/157 reads (43%) | catalogued as COSV55892135; called by muse, varscan2
- FMNL3 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs767828642, COSV53301336, COSV53307501; called by muse, varscan2
- GLB1L3 | c.1274C>G p.S425C | Missense Mutation (SNP) | VAF 122/338 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as COSV68392674; called by muse, mutect2, varscan2
- GPI | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs148548669, COSV62894541; called by muse, mutect2, varscan2
- GPSM1 | c.1634C>T p.S545L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); catalogued as rs782626806, COSV52517439; called by muse, mutect2, varscan2
- GSR | c.647G>A p.S216N | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV55320516; called by muse, mutect2, varscan2
- HAX1 | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV55171916; called by muse, varscan2
- HMGB1 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV58104676; called by muse, mutect2, varscan2
- HYDIN | c.9046G>T p.E3016* | Nonsense Mutation (SNP) | VAF 23/178 reads (13%) | catalogued as COSV99993139; called by muse, varscan2
- IFT122 | c.652C>G p.L218V (on ENST00000348417 / NM_052989.3; = p.L269V on NM_052985.4) | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as COSV56202612, COSV56202967; called by muse, mutect2, varscan2
- IL22RA1 | c.196del p.V66Wfs*16 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | catalogued as COSV54630709; called by mutect2, pindel, varscan2
- IQCB1 | c.1498G>C p.E500Q | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.954); catalogued as COSV60437242; called by muse, mutect2, varscan2
- ITSN2 | c.1337G>C p.R446T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100743967, COSV61946504; called by muse, mutect2, varscan2
- ITSN2 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61946548; called by muse, mutect2, varscan2
- KLHL41 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as COSV52930037; called by muse, mutect2, varscan2
- KMT2D | c.11362C>T p.Q3788* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as COSV56438266; called by muse, mutect2, varscan2
- LAMA4 | c.2050G>C p.E684Q (on ENST00000230538 / NM_001105206.3; = p.E677Q on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV57896044, COSV57897903; called by muse, mutect2, varscan2
- LAMC1 | c.2992G>A p.D998N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.014); catalogued as COSV51139718; called by muse, mutect2, varscan2
- LARS1 | c.45G>C p.K15N | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV50972254, COSV50975165; called by muse, mutect2, varscan2
- LGI3 | c.1575G>T p.Q525H | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV60443282; called by muse, mutect2, varscan2
- LHX8 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53956153, COSV53956261; called by muse, mutect2, varscan2
- LRFN1 | c.1640C>G p.S547W | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50440564; called by muse, mutect2, varscan2
- LRFN1 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1254139255, COSV50442832; called by muse, mutect2
- LRRC4B | c.1316C>T p.T439M | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs755405079, COSV65349952; called by muse, mutect2, varscan2
- MAN2A1 | c.499C>G p.Q167E | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.241); catalogued as rs754621935, COSV54851134; called by muse, mutect2, varscan2
- MARCHF6 | c.1162C>G p.L388V | Missense Mutation (SNP) | VAF 96/298 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.296); catalogued as COSV56880940; called by muse, mutect2, varscan2
- MLH1 | c.762G>C p.K254N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51617490; called by muse, mutect2, varscan2
- MMS22L | c.2612C>T p.S871L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1255466560, COSV51520368; called by muse, mutect2, varscan2
- MYOM1 | c.1411del p.H471Ifs*46 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as COSV99866599; called by mutect2, varscan2
- NDC80 | c.1564G>C p.E522Q | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV55247869; called by muse, mutect2, varscan2
- NFAT5 | c.1257C>G p.I419M | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV63027164; called by muse, mutect2, varscan2
- NOS3 | c.1596G>C p.Q532H | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV52489224; called by muse, mutect2, varscan2
- NPEPL1 | c.325C>G p.R109G | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100622319; called by muse, mutect2
- ODF2L | c.668T>C p.M223T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54015272; called by muse, mutect2, varscan2
- OR4P4 | c.687G>C p.E229D | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV58921766; called by muse, mutect2, varscan2
- OR5F1 | c.334T>C p.C112R | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV53546307; called by muse, mutect2, varscan2
- PARD6A | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54667387; called by muse, mutect2, varscan2
- PARPBP | c.1227A>T p.E409D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.78); catalogued as COSV59673270; called by muse, mutect2, varscan2
- PCDH10 | c.965C>G p.P322R | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.054); catalogued as COSV52092940; called by muse, mutect2, varscan2
- PDE2A | c.2043C>T p.L681= | Splice Region (SNP) | VAF 18/51 reads (35%) | catalogued as rs200284582; called by muse, mutect2, varscan2
- PIANP | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.057); catalogued as rs964594946, COSV100272243, COSV57707879; called by muse, mutect2, varscan2
- PIGN | c.281C>A p.S94Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62949155; called by muse, mutect2, varscan2
- POLD3 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV55242278; called by muse, mutect2, varscan2
- POU6F2 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.278); catalogued as rs1461973335; called by muse, mutect2
- PPM1M | c.355C>G p.L119V (on ENST00000296487; = p.L280V on NM_144641.4) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV56599168; called by muse, mutect2, varscan2
- PRMT5 | c.143C>A p.P48Q | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53545906, COSV53545989; called by muse, mutect2, varscan2
- PSG1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 93/307 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.69); catalogued as rs534643202, COSV54948843; called by muse, mutect2, varscan2
- PSMD11 | c.1123C>T p.H375Y | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1414721405, COSV55578590, COSV55579926; called by muse, mutect2, varscan2
- PSMD6 | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV55759739; called by muse, mutect2, varscan2
- RALGAPA1 | c.4136C>T p.S1379L | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as COSV51881999; called by muse, mutect2, varscan2
- RC3H1 | c.2128G>C p.E710Q | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV51200109; called by muse, mutect2, varscan2
- RDH10 | c.900G>C p.K300N | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV53582123; called by muse, mutect2, varscan2
- REG1B | c.441G>C p.K147N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.243); catalogued as COSV59304813, COSV59305364, COSV59308230; called by muse, mutect2
- RPUSD2 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.95); PolyPhen benign (0.017); catalogued as COSV59765445, COSV59765455; called by muse, mutect2, varscan2
- RTL1 | c.1714G>C p.D572H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66016755; called by muse, mutect2, varscan2
- SEC14L5 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs190855004; called by muse, mutect2, varscan2
- SERPINB3 | c.129A>T p.L43F | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV52191347; called by muse, mutect2, varscan2
- SGF29 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 83/232 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV57681535; called by muse, mutect2, varscan2
- SIK3 | c.1786C>T p.Q596* (on ENST00000445177 / NM_001366686.2; = p.Q602* on NM_025164.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV52618217; called by mutect2, varscan2
- SIPA1L1 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62169895; called by muse, mutect2, varscan2
- SLC17A8 | c.66G>C p.K22N | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV60123566; called by muse, mutect2, varscan2
- SLC25A18 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0.019); catalogued as rs1048012660, COSV53657944; called by muse, mutect2, varscan2
- SMAD2 | c.1091A>C p.Q364P | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.13); catalogued as COSV50998041; called by muse, mutect2, varscan2
- SMC4 | c.2478+3_2478+4del p.X826_splice | Splice Site (DEL) | VAF 5/24 reads (21%) | catalogued as rs749856363; called by pindel, varscan2
- SMCO1 | c.55G>C p.D19H | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV66876866; called by muse, mutect2, varscan2
- SMCR8 | c.2332C>A p.Q778K | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as COSV58177078; called by muse, mutect2, varscan2
- STAG2 | c.462G>A p.E154= | Splice Region (SNP) | VAF 15/20 reads (75%) | catalogued as COSV54357370, COSV54372119; called by mutect2, varscan2
- STK32C | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1406086662, COSV53840316; called by muse, mutect2, varscan2
- SUN1 | c.638C>G p.S213C (on ENST00000405266 / NM_001367651.1; = p.S163C on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/288 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61778095, COSV61778128; called by muse, varscan2
- SWT1 | c.40C>G p.Q14E | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as COSV62254815; called by muse, mutect2, varscan2
- TAS1R1 | c.2007C>G p.F669L | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV59839731; called by muse, mutect2, varscan2
- TASOR | c.1877A>G p.N626S (on ENST00000355628 / NM_001365636.2; = p.N230S on NM_015224.3) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); catalogued as COSV62927649; called by muse, mutect2, varscan2
- TCF12 | c.1217G>C p.R406T | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51005709; called by muse, mutect2, varscan2
- THBS2 | c.2803G>A p.D935N | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64678590; called by muse, mutect2, varscan2
- TLR2 | c.1192C>G p.H398D | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.056); catalogued as COSV52605790, COSV52606082; called by muse, mutect2, varscan2
- TMEM31 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV100128969; called by muse, mutect2
- TNNT1 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV52571633; called by muse, mutect2, varscan2
- TNRC6A | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV59363759; called by muse, mutect2, varscan2
- TOGARAM1 | c.2915C>G p.S972C | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs780990804, COSV63891920; called by muse, mutect2, varscan2
- TRAPPC8 | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51970370; called by muse, mutect2, varscan2
- TRIP11 | c.2959C>G p.Q987E | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV50920286; called by muse, mutect2, varscan2
- TSC1 | c.1729G>T p.E577* | Nonsense Mutation (SNP) | VAF 25/48 reads (52%) | catalogued as rs118203570, CM981936, COSV100051643, COSV99036935; ClinVar: not provided; called by muse, mutect2, varscan2
- UBN2 | c.2587C>G p.Q863E | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as COSV56029953; called by muse, mutect2, varscan2
- UBQLN2 | c.1258C>G p.P420A | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV57739474; called by muse, mutect2, varscan2
- UBR5 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV55285717, COSV55289415; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1360C>T p.Q454* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as rs773648455, COSV99512544; called by muse, mutect2, varscan2
- VNN2 | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV58472385, COSV58474998; called by muse, mutect2, varscan2
- VPS53 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 38/127 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV52130039, COSV52130470; called by muse, mutect2, varscan2
- VPS54 | c.2293G>C p.V765L | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV55440325; called by muse, mutect2, varscan2
- XRN1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53811198; called by muse, mutect2, varscan2
- ZC3H12B | c.2241G>C p.L747F | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59047648; called by muse, mutect2, varscan2
- ZNF226 | c.1223C>G p.S408C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV56196537, COSV56197956; called by muse, mutect2, varscan2
- ZNF236 | c.1963A>G p.R655G | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53487271; called by muse, mutect2, varscan2
- ZNF236 | c.1964G>A p.R655K | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); catalogued as COSV53487295; called by muse, mutect2, varscan2
- ZNF454 | c.932G>T p.C311F | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.765); catalogued as COSV60768243; called by muse, mutect2, varscan2
- ZNF777 | c.389A>C p.H130P | Missense Mutation (SNP) | VAF 104/314 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as COSV56097416; called by muse, varscan2
- ACACA | c.1811G>A p.R604K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- APOC1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- BCL2L10 | c.537G>T p.W179C | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDKN1A | c.132_133dup p.A45Gfs*104 | Frame Shift Ins (INS) | VAF 10/49 reads (20%) | called by mutect2, pindel, varscan2
- DCLRE1A | c.488C>G p.S163* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- ERGIC2 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 47/147 reads (32%) | called by muse, mutect2, varscan2
- FOXA1 | c.726del p.Y243Tfs*78 | Frame Shift Del (DEL) | VAF 41/89 reads (46%) | called by mutect2, pindel, varscan2
- KMT2C | c.13724_13728del p.L4575Pfs*5 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- KMT2C | c.7221del p.S2408Hfs*44 | Frame Shift Del (DEL) | VAF 106/362 reads (29%) | called by mutect2, pindel, varscan2
- MRPS5 | c.916A>T p.K306* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- NCOA1 | c.2269G>T p.E757* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- NGEF | c.2008_2010del p.E670del | In Frame Del (DEL) | VAF 42/141 reads (30%) | called by pindel, varscan2
- PLCB3 | c.2804C>T p.P935L | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- SAMD11 | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- SIM1 | c.744-1G>C p.X248_splice | Splice Site (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- SUGP2 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- UNC5CL | c.1351_1359delinsGG p.R451Gfs*23 | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | called by pindel, varscan2*
- VPS9D1 | c.432-1G>A p.X144_splice | Splice Site (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2
- ADAM32 | c.996C>T p.D332= | Silent (SNP) | VAF 105/140 reads (75%) | catalogued as rs368424322; called by muse, mutect2, varscan2
- ANK3 | c.5505A>T p.A1835= | Silent (SNP) | VAF 55/215 reads (26%) | catalogued as COSV55056049; called by muse, mutect2, varscan2
- AP5Z1 | c.2037C>T p.F679= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs569992088, COSV62240733; called by muse, mutect2, varscan2
- ARMC4 | c.2586C>G p.L862= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs1172411870, COSV59456735, COSV59462668; called by muse, mutect2, varscan2
- B4GALNT4 | c.1293G>A p.P431= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs767838226, COSV57323080; called by muse, mutect2, varscan2
- CAPN13 | c.1455C>T p.S485= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV54430186; called by muse, mutect2, varscan2
- CDH11 | c.459T>C p.N153= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV51760281; called by muse, mutect2, varscan2
- CLEC10A | c.510C>T p.L170= (on ENST00000254868 / NM_182906.4; = p.L143= on NM_006344.4) | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV54701027; called by muse, mutect2, varscan2
- CSMD3 | c.4599C>T p.V1533= (on ENST00000297405 / NM_001363185.1; = p.V1429= on NM_052900.3) | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV52167713; called by muse, mutect2, varscan2
- CYP3A4 | c.381G>A p.K127= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as COSV60501824; called by muse, mutect2, varscan2
- DDX20 | c.1332G>C p.L444= | Silent (SNP) | VAF 39/118 reads (33%) | catalogued as rs1171849446, COSV63778998; called by muse, mutect2, varscan2
- DISP3 | c.807G>A p.T269= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV53826325; called by muse, mutect2, varscan2
- FAM151B | c.147G>C p.L49= | Silent (SNP) | VAF 42/76 reads (55%) | catalogued as COSV56472954; called by muse, mutect2, varscan2
- FANCA | c.1806G>A p.A602= | Silent (SNP) | VAF 48/139 reads (35%) | catalogued as rs550064744, COSV66880841; called by muse, mutect2, varscan2
- FANCA | c.1098G>A p.L366= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as COSV66881457, COSV66883819; called by muse, mutect2, varscan2
- GAD2 | c.924G>T p.G308= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV52156447; called by muse, mutect2, varscan2
- GAS2L2 | c.183G>A p.T61= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs1319930070; called by muse, mutect2, varscan2
- GSTP1 | c.570C>G p.L190= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs1247344619, COSV66992406; called by muse, varscan2
- HELZ | c.4545C>T p.F1515= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as rs766115191, COSV62378120; called by muse, mutect2, varscan2
- IPO8 | c.2232C>T p.V744= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as COSV56241343; called by muse, mutect2, varscan2
- KCNS1 | c.1170C>T p.F390= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV60260067; called by muse, mutect2, varscan2
- LCT | c.4455C>A p.I1485= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs1414364945, COSV51548401; called by muse, mutect2, varscan2
- MYF5 | c.372C>G p.L124= | Silent (SNP) | VAF 55/143 reads (38%) | catalogued as COSV57355003; called by muse, mutect2, varscan2
- MYO5B | c.4113G>A p.E1371= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV53217764; called by muse, mutect2, varscan2
- OBSCN | c.19698C>T p.V6566= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV62402129; called by muse, mutect2, varscan2
- OR10G4 | c.384G>A p.P128= | Silent (SNP) | VAF 61/243 reads (25%) | catalogued as rs765160603, COSV57977497; called by muse, mutect2, varscan2
- PDE12 | c.1116G>A p.G372= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV60818569; called by muse, mutect2, varscan2
- PLCB3 | c.3387C>T p.I1129= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as COSV54188135; called by muse, mutect2, varscan2
- PLXNB2 | c.4479G>A p.K1493= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV63781365; called by muse, mutect2, varscan2
- PTGDR2 | c.885C>T p.F295= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99920115; called by muse, mutect2
- RAD54B | c.2187C>A p.L729= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV60251012; called by muse, varscan2
- REN | c.924C>T p.L308= | Silent (SNP) | VAF 105/474 reads (22%) | catalogued as COSV65817713; called by muse, mutect2, varscan2
- SF3B2 | c.2289C>G p.L763= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV59427831; called by muse, mutect2, varscan2
- SIK3 | c.1785G>T p.V595= (on ENST00000445177 / NM_001366686.2; = p.V601= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV52613583; called by muse, varscan2
- SLC49A4 | c.1335C>T p.F445= | Silent (SNP) | VAF 109/307 reads (36%) | catalogued as COSV53746780; called by muse, mutect2, varscan2
- SUPT7L | c.258G>A p.Q86= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV58134694; called by muse, mutect2, varscan2
- TFAP2C | c.216G>A p.S72= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV52370277, COSV52371299; called by muse, mutect2, varscan2
- TMEM94 | c.2790C>T p.I930= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV58595232; called by muse, mutect2, varscan2
- TTLL8 | c.1515C>T p.H505= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs373978372, COSV99838352; called by muse, mutect2, varscan2
- ZFAND1 | c.435G>A p.L145= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV55107533; called by muse, mutect2, varscan2
- ZNF682 | c.300G>T p.L100= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV62066254, COSV62066884; called by muse, mutect2, varscan2
- CIT | c.2082+1912G>A | Intron (SNP) | VAF 30/109 reads (28%) | catalogued as rs762975110, COSV55866306; called by muse, mutect2, varscan2
- OR52A4P | n.815T>A | RNA (SNP) | VAF 18/72 reads (25%) | called by muse, mutect2, varscan2
- OSTCP1 | n.499C>T | RNA (SNP) | VAF 34/124 reads (27%) | called by muse, mutect2, varscan2
- PRDM15 | c.-561C>T | 5'UTR (SNP) | VAF 13/19 reads (68%) | catalogued as rs75817094, COSV54152151, COSV54158762; called by muse, mutect2, varscan2
